Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MV, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MV-01A (Primary Tumor).

[page 1 of 3]
Specimen:	Patient:	
Procedure:	Medical Record #:	Account #:
Accessioned:	DOB/Age/Sex:	(Age: F
Reported:	Location/Client:	
Submitting Phys:		

Surgical Pathology Report

**** Corrected -- Minor revisions do not affect Final Diagnosis ****

Amendments

Report Amended on

Reason: Correct/Add Specimen Information

Previous Signout Date:

Final Diagnosis

"ADRENAL MASS" (A) AND "RETROPERITONEAL LYMPH NODE" (B):

- PARAGANGLIOMAS, 4.4 CM (A) AND 0.8 CM (B) IN GREATEST DIMENSIONS RESPECTIVELY. NO ADRENAL (A) OR LYMPH NODE TISSUE (B) IS IDENTIFIED. BOTH SPECIMENS ARE SUBMITTED ENTIRELY FOR EVALUATION.
- THE TUMOR CELLS STAIN POSITIVELY FOR CHROMOGRANIN, SYNAPTOPHYSIN AND NSE AND ARE NEGATIVE FOR EMA AND ACTH. THE SUSTENTACULAR CELLS ARE POSITIVE FOR S-100.
- BOTH LESIONS ARE ENTIRELY ENCAPSULATED. NO VASCULAR INVASION OR TUMOR NECROSIS IS IDENTIFIED. THE PROLIFERATIVE INDEX USING THE MIB-1 (KI 67) IMMUNOSTAIN IS < 1%.

WHIPPLE'S RESECTION (F):

- DUODENAL CARCINOIDS, TWO, 1.1 CM (F19, 20) AND 2 CM (F11-16) IN GREATEST DIMENSION RESPECTIVELY WITH INFILTRATION INTO THE MUSCULARIS PROPRIA, FOCAL PSAMMOMATOUS CALCIFICATION (F11) AND NODAL METASTASIS TO 2/5 PERIPANCREATIC NODES (F7 AND 8), WITH FOCAL EXTRANODAL EXTENSION.
- THE TUMOR CELLS ARE DIFFUSELY POSITIVE FOR CHROMOGRANIN, SYNAPTOPHYSIN AND SOMATOSTATIN AND FOCALLY POSITIVE FOR S-100, GASTRIN AND CK7. IMMUNOHISTOCHEMICAL STAINS FOR GLUCAGON, INSULIN, PANCREATIC POLYPEPTIDE, SEROTONIN, ACTH AND CK20 ARE NEGATIVE. (SEE COMMENT).
- PROXIMAL AND DISTAL RESECTION MARGINS AND THE PANCREAS ARE FREE OF TUMOR.
- BILE DUCT RESECTION MARGIN SHOWS PROMINENT ACUTE INFLAMMATION WITH REACTIVE ATYPIA OF THE LINING EPITHELIUM (F10). THERE IS NO EVIDENCE OF MALIGNANCY.
- FOUR PERIDUODENAL LYMPH NODES, THERE IS NO EVIDENCE OF MALIGNANCY.

COMMENT: The synchronous occurrence of multiple paragangliomas and duodenal somatostatinomas in this case suggests possibilities of neurofibromatosis type I (Ref. Histopathology 1987; 11:1331-40) or Von-Hippel-Lindau disease (Ref. Internal Medicine 2001; 40:38-43).

NECK OF PANCREAS (C) AND UNCINATE PROCESS (G):

- PANCREATIC TISSUE, THERE IS NO EVIDENCE OF MALIGNANCY.

BILE DUCT (D):

- BILIARY EPITHELIUM WITH ACUTE INFLAMMATION AND FOCAL REACTIVE ATYPIA. THERE IS NO EVIDENCE OF MALIGNANCY.

GALLBLADDER (E):

[page 2 of 3]
- CHRONIC CHOLECYSTITIS, MILD.
- THERE IS NO EVIDENCE OF MALIGNANCY.

***Report Electronically Signed

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Intra-Operative Consultation with Frozen Section

FROZEN SECTION DIAGNOSIS: ADRENAL MASS, (AFS):

- POSITIVE FOR MALIGNANCY, CONSISTENT WITH ENDOCRINE NEOPLASIA.

FROZEN SECTION DIAGNOSIS: RETROPERITONEAL LYMPH NODE (BFS):

- POSITIVE FOR MALIGNANCY.

FROZEN SECTION DIAGNOSIS: NECK OF PANCREAS (CFS):

- NEGATIVE FOR MALIGNANCY.

FROZEN SECTION DIAGNOSIS: BILE DUCT (DFS):

- NEGATIVE FOR MALIGNANCY.

Clinical History

Pancreatic tumor

Pre-Operative Diagnosis

(Not Provided)

Post-Operative Diagnosis

(Not Provided)

Gross Description

A. ADRENAL MASS (FRESH): The specimen, labeled with the patient's name and accession number, consists of a cystic lesion, measuring 4.4 x 3.8 x 3 cm, surrounded by a narrow rim of tan-yellow tissue measuring 0.3 cm in average thickness. The external surface is smooth and inked black. The cut surface is tan-gray and has multiple friable tan-brown focally hemorrhagic papillary projections. One tissue fragment has been frozen for intraoperative diagnosis. Three touch preps were made. One tissue fragment has been sent for cytogenetics. The remainder is submitted entirely in cassettes A1-A14.

B. RETROPERITONEAL LYMPH NODE (FRESH): The specimen, labeled with the patient's name and accession number, consists of two fragments of tan-gray tissue. One fragment is round, firm, nodule, measuring 0.8 cm in greatest diameter. Serial sectioning reveals white surface with focal hemorrhage. One-half of the nodule is frozen for intraoperative diagnosis. The second fragment consists of friable tissue, measuring 1 x 0.7 x 0.8 cm. One tissue fragment is snap frozen. The specimen is submitted entirely as follows:

SECTION CODE

- B1: RESIDUAL TISSUE AFTER FROZEN SECTION.
- B2: THE SECOND HALF OF THE NODULE.
- B3: REMAINDER OF THE SPECIMEN.

C. NECK OF PANCREAS (FRESH): The specimen, labeled with the patient's name and accession number, is a single fragment of tan gray lobulated rubbery tissue, measuring 1.7 x 1 x 0.5 cm in greatest dimension. No gross lesions are seen. The specimen is frozen entirely for intraoperative diagnosis. The residual tissue after frozen section is submitted in cassette C1.

D. BILE DUCT (FRESH): The specimen, labeled with the patient's name and accession number, is a single fragment of tan gray rubbery tissue, measuring 1.2 x 0.6 x 0.5 cm. The specimen is frozen in toto for intraoperative diagnosis. The residual tissue after frozen section is submitted in cassette D1.

[page 3 of 3]
E. GALLBLADDER (FRESH): The specimen, labeled with the patient's name and accession number is a 6 x 3 x 0.4 cm (wall thickness) gallbladder with a green velvety mucosa without any ulcerations. No wall thickening is identified. The serosal surface is smooth and glistening. There are no gallstones present. Representative sections are submitted in cassette E1.

F. WHIPPLE (FRESH): The specimen, labeled with the patient's name and accession number, is stomach (9.5 cm in length x 5.4 cm in circumference x 0.5 cm wall thickness) with stapled incision (6 cm in length), duodenum (15 cm in length x 6 cm in circumference) and pancreatic head (9 x 4.5 x 4 cm). The pancreatic parenchyma is grossly unremarkable, external surface is inked black. There is a peripancreatic nodule, measuring 1 cm in greatest diameter. Sectioning reveals tan-white cut surface with focal hemorrhage. The main pancreatic duct and the common bile duct have a smooth tan-gray mucosa. No dilatation is seen. There is a round, firm, tan-white submucosal nodule, and measuring 3 cm in greatest diameter present under the ampulla of Vater. A similar submucosal lesion is present 1 cm proximal to the ampulla and measuring 1.1 cm in greatest dimension. The gastric mucosa is unremarkable. The distal 7 cm of the duodenal mucosa is red-brown, congested. Two lymph nodes are found inferior duodenal soft tissue. Representative sections are submitted as follows:

SECTION CODE

- F1: DISTAL RESECTION MARGIN.
- F2: PROXIMAL RESECTION MARGIN.
- F3-9: RANDOM SECTIONS OF THE PANCREAS (NODULE IN F7 AND F8).
- F10: PROXIMAL BILE DUCT RESECTION MARGIN.
- F11-17: REPRESENTATIVE LONGITUDINAL SECTION OF THE PANCREATIC BILE DUCT AND AMPULLA OF VATER (AMPULLARY SUBMUCOSAL NODULE IN F11-F14).
- F18: ADJACENT TO THE DUCT PANCREATIC TISSUE.
- F19-20: DUODENAL NODULE, PROXIMAL TO AMPULLA.
- F21-22: REPRESENTATIVE SECTIONS OF DUODENUM.
- F23: ANTRUM.
- F24: RANDOM SECTION OF STOMACH.
- F25-26: DUODENAL MESENTERY WITH LYMPH NODES.

G. UNCINATE (FRESH): The specimen, labeled with the patient's name and accession number is a single fragment of fibroadipose tissue measuring 1.8 x 1.2 x 0.5 cm with suture at one edge. No gross lesions are seen. The sutured end is inked black. The specimen is submitted in toto in cassette G1.

Immunohistochemical staining performed in this case may involve reagents labeled as analyte specific reagents. For these cases: This test was developed and its performance characteristics determined by Department of Pathology. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Department of Pathology
- End of Report -

Page 3 of 3

Printed:

Source: NCI Genomic Data Commons file beaf96c7-3893-430b-b04b-27f6805f6eb2 (TCGA-SR-A6MV.2FABA354-85EC-48C7-8C0F-BBEDDCA3E541.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).